Somatic mutation profile of tumor specimen TCGA-AA-3872-01A (aliquot TCGA-AA-3872-01A-01W-0995-10) from TCGA case TCGA-AA-3872, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 45.6 years (16,651 days).
Specimen TCGA-AA-3872-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c46369a8-76f2-4244-b45b-5108067d083e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3872-10A (Blood Derived Normal), aliquot TCGA-AA-3872-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f67a5417-7f4d-45c9-b686-4181fec6e118

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 21, Nonsense Mutation 4, Frame Shift Del 3, RNA 2, Splice Site 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375+1del p.X125_splice | Splice Site (DEL) | VAF 18/50 reads (36%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by mutect2, varscan2
- A2M | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 191/415 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1259395599, COSV59385400; called by muse, mutect2, varscan2
- ADAMTS20 | c.4543C>T p.Q1515* | Nonsense Mutation (SNP) | VAF 141/312 reads (45%) | catalogued as COSV101238988, COSV67131277; called by muse, mutect2, varscan2
- APBA2 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs145494651; called by muse, mutect2, varscan2
- APC | c.4314del p.P1439Lfs*34 | Frame Shift Del (DEL) | VAF 22/32 reads (69%) | catalogued as COSV57354045, COSV57378825; called by mutect2, varscan2
- ARHGAP20 | c.2608A>G p.K870E | Missense Mutation (SNP) | VAF 25/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52818545; called by muse, mutect2
- CGNL1 | c.3010C>T p.R1004* | Nonsense Mutation (SNP) | VAF 25/95 reads (26%) | catalogued as rs142707768, COSV99847137; called by muse, mutect2, varscan2
- CLEC5A | c.515C>G p.A172G | Missense Mutation (SNP) | VAF 44/566 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV101407775; called by muse, mutect2
- CUBN | c.5208G>A p.S1736= | Splice Region (SNP) | VAF 46/124 reads (37%) | catalogued as rs750853231, COSV64729254; called by muse, mutect2, varscan2
- DGKI | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 66/458 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.343); catalogued as rs1356488881; called by muse, mutect2, varscan2
- ELF3 | c.916del p.L306Cfs*19 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as COSV62838397; called by mutect2, varscan2
- EYA1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 278/1320 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); catalogued as rs373250373; called by mutect2, varscan2
- FAM189A2 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.726); catalogued as COSV57384348; called by muse, mutect2, varscan2
- ITGA5 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1428702198; called by muse, varscan2
- KCNQ4 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV61275446; called by muse, mutect2, varscan2
- KLHDC2 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV53588683; called by muse, mutect2
- LAD1 | c.53G>A p.R18K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0.201); catalogued as rs1235521613, COSV100943755; called by muse, mutect2
- LBP | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.136); catalogued as COSV54144780; called by muse, mutect2, varscan2
- LRRC4B | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV65350117; called by muse, mutect2
- NAPEPLD | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 75/478 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201645773; called by muse, mutect2, varscan2
- OPN5 | c.538G>A p.G180R | Missense Mutation (SNP) | VAF 87/1058 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1008543429, COSV55244102; called by muse, mutect2
- OR8H2 | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57946747; called by muse, mutect2
- PRRC2C | c.7825C>A p.P2609T (on ENST00000367742; = p.P2607T on NM_015172.4) | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100145531; called by muse, varscan2
- PTPRS | c.4810G>A p.A1604T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377564137; called by muse, varscan2
- RCHY1 | c.682C>T p.R228* | Nonsense Mutation (SNP) | VAF 30/89 reads (34%) | catalogued as rs1180170921, COSV61009811; called by muse, mutect2, varscan2
- RXFP3 | c.147G>C p.W49C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV57508777; called by muse, mutect2, varscan2
- SCN7A | c.1523A>C p.D508A | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69275523; called by muse, mutect2, varscan2
- SMARCA1 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV100946523; called by muse, mutect2
- SMC1B | c.3562G>A p.E1188K | Missense Mutation (SNP) | VAF 32/861 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV53415957; called by muse, mutect2
- ST8SIA4 | c.4C>T p.R2C | Missense Mutation (SNP) | VAF 16/276 reads (6%) | PolyPhen probably damaging (0.973); catalogued as rs1412320214, COSV51506099; called by muse, mutect2
- TGM7 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs539233935, COSV71773149; called by muse, mutect2, varscan2
- THSD7A | c.506C>A p.A169E | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs767395309, COSV70273978; called by muse, mutect2, varscan2
- TRIOBP | c.1478G>A p.S493N | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as rs4821700; ClinVar: likely benign / benign; called by muse, varscan2
- TSGA10 | c.1913G>A p.R638H | Missense Mutation (SNP) | VAF 457/734 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs758374278, COSV100747479; called by muse, mutect2, varscan2
- TTC31 | c.1018C>T p.R340W | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs755181077; called by muse, mutect2, varscan2
- XPNPEP1 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 124/222 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59171656; called by muse, mutect2, varscan2
- ZNF711 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.515); catalogued as rs1427911141, COSV52156083; called by muse, mutect2
- ADGRB3 | c.260C>A p.A87D | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ANK3 | c.8251dup p.I2751Nfs*14 | Frame Shift Ins (INS) | VAF 58/240 reads (24%) | called by mutect2, varscan2
- ANKIB1 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 113/466 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ANKRD11 | c.3344del p.I1115Tfs*203 | Frame Shift Del (DEL) | VAF 43/186 reads (23%) | called by mutect2, varscan2
- ARMCX1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- C12orf40 | c.1295T>G p.I432R | Missense Mutation (SNP) | VAF 176/528 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CACNA1E | c.1322C>A p.P441H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDH12 | c.1414A>G p.K472E | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CFHR4 | c.1640T>G p.F547C (on ENST00000367416 / NM_001201551.2; = p.F301C on NM_006684.5) | Missense Mutation (SNP) | VAF 8/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DRAM1 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 28/946 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- GRM1 | c.1964C>A p.T655N | Missense Mutation (SNP) | VAF 85/816 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- IL1RL1 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 50/1302 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2
- KPNA4 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- LRRN3 | c.1720G>C p.D574H | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- NELL2 | c.606+2T>A p.X202_splice | Splice Site (SNP) | VAF 64/352 reads (18%) | called by muse, mutect2, varscan2
- PRUNE2 | c.4956T>G p.H1652Q | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RASAL2 | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.87); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RIMS2 | c.2298T>G p.Y766* (on ENST00000666250 / NM_001348490.2; = p.Y574* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 24/400 reads (6%) | called by muse, mutect2
- RNF17 | c.2510T>C p.V837A | Missense Mutation (SNP) | VAF 508/1394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SDK2 | c.4283G>A p.G1428E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- SERPINE1 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TRPC5 | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.263); called by muse, mutect2
- ADGRG6 | c.3549C>T p.T1183= | Silent (SNP) | VAF 22/231 reads (10%) | catalogued as COSV51602935; called by muse, mutect2, varscan2
- CACNA1E | c.4590C>T p.I1530= | Silent (SNP) | VAF 299/1305 reads (23%) | catalogued as rs776940576, COSV62392343; called by muse, mutect2, varscan2
- DNAH9 | c.7512C>T p.N2504= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs199937308, COSV52340966; called by muse, mutect2, varscan2
- EPG5 | c.171A>T p.G57= | Silent (SNP) | VAF 30/67 reads (45%) | catalogued as COSV56357432; called by muse, mutect2, varscan2
- FANCM | c.2997G>A p.P999= | Silent (SNP) | VAF 62/236 reads (26%) | catalogued as rs141430587; called by muse, mutect2, varscan2
- GFPT2 | c.1872C>T p.D624= | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as rs371527867; ClinVar: likely benign; called by muse, mutect2, varscan2
- INHBC | c.69C>T p.G23= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs771981139, COSV59006445; called by muse, mutect2, varscan2
- LAD1 | c.52A>C p.R18= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2
- MEFV | c.807G>A p.A269= | Silent (SNP) | VAF 31/136 reads (23%) | catalogued as COSV54828834; called by muse, mutect2, varscan2
- NLRP4 | c.1251C>T p.D417= | Silent (SNP) | VAF 79/259 reads (31%) | catalogued as rs376218682, COSV56714165; called by muse, mutect2, varscan2
- NTNG2 | c.429C>T p.Y143= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as COSV62366046; called by muse, mutect2, varscan2
- OR52L1 | c.51C>T p.L17= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs758339164, COSV59988519; called by muse, mutect2, varscan2
- PDZRN4 | c.1419C>T p.N473= (on ENST00000402685 / NM_001164595.2; = p.N215= on NM_013377.4) | Silent (SNP) | VAF 128/490 reads (26%) | catalogued as rs772211469, COSV54220398; called by muse, mutect2, varscan2
- PLEKHG4B | c.1506C>T p.S502= (on ENST00000283426; = p.S858= on NM_052909.5) | Silent (SNP) | VAF 3/25 reads (12%) | catalogued as rs373547646; called by muse, mutect2
- PLEKHG6 | c.823C>A p.R275= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV50617807; called by muse, mutect2, varscan2
- ROBO1 | c.3978G>A p.A1326= | Silent (SNP) | VAF 86/270 reads (32%) | catalogued as rs775159753, COSV71392563; called by muse, mutect2, varscan2
- SEC11C | c.252C>T p.F84= | Silent (SNP) | VAF 16/442 reads (4%) | called by muse, mutect2
- TASOR | c.3216C>T p.L1072= (on ENST00000355628 / NM_001365636.2; = p.L696= on NM_015224.3) | Silent (SNP) | VAF 15/135 reads (11%) | catalogued as COSV100843261, COSV62930235; called by muse, mutect2, varscan2
- TLL1 | c.2799C>T p.F933= | Silent (SNP) | VAF 21/411 reads (5%) | called by muse, mutect2
- USP45 | c.135C>T p.I45= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- WIPF3 | c.1257C>T p.F419= | Silent (SNP) | VAF 73/702 reads (10%) | catalogued as rs367957588; called by muse, mutect2, varscan2
- LINC02145 | n.411C>T | RNA (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- MIR519D | n.30G>A | RNA (SNP) | VAF 257/994 reads (26%) | catalogued as rs765688484; called by muse, mutect2, varscan2
